Surgical pathology report (de-identified scan), TCGA case TCGA-49-4501, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4501-01A (Primary Tumor).

FINAL DIAGNOSIS -----
RIGHT LUNG, UPPER LOBE (LOBECTOMY): INFILTRATING MODERATELY
DIFFERENTIATED ADENOCARCINOMA WITH BRONCHIOLOALVEOLAR FEATURES (2.8
cm). THE CARCINOMA EXTENDS INTO THE PLEURA. FIVE (5) HILAR LYMPH
NODES ARE NEGATIVE FOR TUMOR. BRONCHIAL AND VASCULAR MARGINS OF
RESECTION ARE NEGATIVE FOR TUMOR. NON-NEOPLASTIC LUNG WITH
CONGESTION, EDEMA, AND FOCAL HEMORRHAGE. SEE NOTE.
NOTE: The pathologic stage for this carcinoma is pT2pN0pMX or Stage I.

Source: NCI Genomic Data Commons file 83d387d0-5426-4143-b277-83b3b6cf9fb5 (TCGA-49-4501.DA1BF563-9AD3-49CF-A68A-44AF8ED41684.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).